Somatic mutation profile of tumor specimen BLGSP-71-19-00108-01A (aliquot BLGSP-71-19-00108-01A-11D-A671-33) from CGCI case BLGSP-71-19-00108, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: female; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 15.9 years (5,803 days).
Specimen BLGSP-71-19-00108-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Spleen; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec803704-87bd-4a0b-9a99-5af3ada24cd6.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-19-00108-16A (Mononuclear Cells from Bone Marrow Normal), aliquot BLGSP-71-19-00108-16A-01D-A671-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb98c6bc-cd76-436a-abf3-48ce17c3109b

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | hotspot (GDC flag); catalogued as rs1131691026, CM101750, COSV52661500, COSV52987374, COSV53571745; ClinVar: pathogenic; called by muse, mutect2
- NOTCH2 | c.3440A>T p.E1147V | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56686111; called by muse, mutect2
- FBXO11 | c.1766T>A p.I589N (on ENST00000403359 / NM_001190274.2; = p.I505N on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/317 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- FSIP2 | c.2365A>C p.S789R | Missense Mutation (SNP) | VAF 31/566 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- P2RY8 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- REL | c.1786C>G p.Q596E | Missense Mutation (SNP) | VAF 54/578 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); called by muse, mutect2
- TANC1 | c.4226T>A p.L1409H | Missense Mutation (SNP) | VAF 28/462 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- VCAN | c.6148A>G p.T2050A | Missense Mutation (SNP) | VAF 24/458 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
